Gene-level copy-number profile of tumor specimen TCGA-DX-A3U6-01A from TCGA case TCGA-DX-A3U6, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.5 years (23,193 days).
Specimen TCGA-DX-A3U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.377047a2-2510-4c52-b73d-6766bcf14a18.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3U6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f699c2d-9bb9-468e-b4b8-f5062d0e519e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 75; copy number 2: 59,023; copy number 3: 211; copy number 4: 322; copy number 5: 43; copy number 6: 36; copy number 7: 27; copy number 8: 40; copy number 9: 8; copy number 10: 4; copy number 11: 16; copy number 12: 1; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3U6-01A-11D-A29M-01): tumor purity 0.2, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 176 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:166,275,629–166,277,597, 1 gene, copy number 6: AL596087.1.
- chr1:170,532,131–171,251,857, 8 genes, copy number 6 (within-gene range 2–6): GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1.
- chr1:171,392,229–171,638,799, 4 genes, copy number 8 (within-gene range 4–8): GM2AP2, CYCSP53, PRRC2C, MYOCOS.
- chr1:171,841,498–172,418,466, 1 gene, copy number 11 (within-gene range 2–11): DNM3.
- chr1:172,138,397–172,213,499, 5 genes, copy number 11: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr1:201,283,452–201,332,993, 1 gene, copy number 8 (within-gene range 2–8): PKP1.
- chr3:77,092,057–77,092,163, 1 gene, copy number 5: RNU6-386P.
- chr6:121,354,354–121,858,768, 14 genes, copy number 5: RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18.
- chr6:148,237,585–149,485,014, 18 genes, copy number 6 (within-gene range 2–6): AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1, SUMO4, ZC3H12D.
- chr7:10,702,676–10,940,735, 4 genes, copy number 7: AC004415.1, Y_RNA, NDUFA4, AC007029.1.
- chr7:11,180,902–11,520,175, 1 gene, copy number 5 (within-gene range 2–5): AC004160.1.
- chr7:11,370,365–11,832,198, 3 genes, copy number 5: THSD7A, AC004160.2, THRAP3P3.
- chr12:57,612,118–58,395,138, 36 genes, copy number 5–8 (within-gene range 4–8): AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:59,322,765–59,524,184, 5 genes, copy number 6–12 (within-gene range 2–12): AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448.
- chr12:64,222,337–64,397,065, 1 gene, copy number 5 (within-gene range 2–5): AC012158.1.
- chr12:64,264,762–64,502,114, 8 genes, copy number 5 (within-gene range 3–5): C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1.
- chr12:65,050,626–65,491,430, 8 genes, copy number 5 (within-gene range 3–5): WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:65,758,020–65,966,291, 5 genes, copy number 6 (within-gene range 2–6): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:67,269,358–67,729,475, 10 genes, copy number 11 (within-gene range 2–11): CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421.
- chr12:68,674,371–68,850,686, 10 genes, copy number 8–10: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,400,903–69,610,907, 8 genes, copy number 9: RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10.
- chr12:72,046,149–72,057,377, 1 gene, copy number 14 (within-gene range 2–14): AC090109.1.
- chr20:40,685,848–41,712,600, 23 genes, copy number 7: MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1.

Autosomal genes at a single copy (total copy number 1): 75. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
